Gene-level copy-number profile of tumor specimen TCGA-CD-5800-01A from TCGA case TCGA-CD-5800, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage II; Tumor grade: G1.
Specimen TCGA-CD-5800-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.e6ccbc71-0df6-42a2-83fe-fad6f7d58463.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CD-5800-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/201205e0-20e7-4a0b-a404-2dc898d91ff3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 366; copy number 2: 13,928; copy number 3: 26,261; copy number 4: 10,211; copy number 5: 4,608; copy number 6: 3,343; copy number 7: 427; copy number 8: 303; copy number 9: 76; copy number 10: 19; copy number 12: 60; copy number 13: 74; copy number 16: 16; copy number 18: 3; copy number 19: 12; copy number 20: 12; copy number 21: 66; copy number 45: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CD-5800-01A-11D-1599-01): tumor purity 0.47, ploidy 3.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,094 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:234,669,523–234,980,804, 10 genes, copy number 7 (within-gene range 4–7): AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3.
- chr3:193,740,471–194,260,720, 16 genes, copy number 8 (within-gene range 5–8): RN7SL447P, AC069421.1, AC069421.2, AC069421.3, LINC02038, LINC02026, AC024559.1, DPPA2P3, LINC02028, AC024559.2, AC080129.1, AC080129.2, HES1, RN7SL215P, LINC02036, LINC02037.
- chr5:218,298–1,728,172, 57 genes, copy number 9 (within-gene range 3–9): AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457, CLPTM1L, AC026748.7, LINC01511, MTCO2P32, AC026748.3, SLC6A3, LPCAT1, MIR6075, AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2, AC026412.4, MIR4277, AC112176.1.
- chr8:65,591,850–68,237,032, 49 genes, copy number 8 (within-gene range 6–8): AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1, PDE7A, AC100812.1, DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P, MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1, CPA6, NACAP10, AC022874.1, NDUFS5P6, PREX2, AC011853.2, AC011853.1.
- chr13:108,596,152–114,337,626, 121 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr14:25,647,304–27,295,516, 14 genes, copy number 8–20 (within-gene range 3–20): LINC02306, AL359396.1, AL359396.2, AL132633.1, CYB5AP5, NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307.
- chr14:67,819,779–68,736,678, 14 genes, copy number 10 (within-gene range 3–10): RAD51B, AL133370.2, AL133370.1, RN7SL706P, RN7SL108P, AL122013.1, PPIAP6, AL121820.3, AL121820.2, AL121820.1, RPL12P7, AL133313.1, AL132986.1, RNU6-921P.
- chr15:84,053,113–86,116,747, 75 genes, copy number 8–12 (broad region; genes not listed).
- chr15:86,138,269–86,173,270, 3 genes, copy number 8: RNA5SP400, AC016180.2, AC016180.1.
- chr17:39,566,915–42,155,044, 169 genes, copy number 7–16 (broad region; genes not listed).
- chr18:7,995,570–8,155,070, 4 genes, copy number 10: U3, AP005900.1, AC006566.2, AC006566.1.
- chr18:13,514,520–13,726,663, 5 genes, copy number 16–18 (within-gene range 2–18): AP005131.1, AP005131.3, MIR4526, AP001010.1, FAM210A.
- chr18:26,952,201–26,952,558, 1 gene, copy number 10: ATP6V1E1P2.
- chr18:30,290,161–30,414,073, 2 genes, copy number 9: AC115100.1, MIR302F.
- chr18:33,552,123–43,499,836, 94 genes, copy number 7–13 (broad region; genes not listed).
- chr19:5,558,167–6,205,121, 33 genes, copy number 8: TINCR, SNRPEP4, SAFB2, SAFB, RPL36, MICOS13, HSD11B1L, LONP1, CATSPERD, PRR22, AC011499.1, DUS3L, NRTN, FUT6, FUT3, AC024592.2, FUT5, AC024592.3, NDUFA11, AC024592.1, AC104532.1, VMAC, AC104532.2, CAPS, RANBP3, AC011444.1, RFX2, AC011444.2, AC011444.4, AC011444.3, ACSBG2, AC011471.1, AC011471.4.
- chr19:10,251,901–12,237,767, 122 genes, copy number 7–21 (broad region; genes not listed).
- chr19:14,254,189–15,950,350, 91 genes, copy number 7 (broad region; genes not listed).
- chr19:19,385,826–19,508,931, 1 gene, copy number 8 (within-gene range 4–8): GATAD2A.
- chr19:19,435,063–20,571,095, 63 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr19:21,318,161–23,147,221, 90 genes, copy number 7 (broad region; genes not listed).
- chr19:28,683,071–30,228,715, 38 genes, copy number 19–45: AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1.
- chr20:50,040,716–50,691,542, 22 genes, copy number 7 (within-gene range 5–7): TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2.

Autosomal genes at a single copy (total copy number 1): 366. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
